Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OE, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OE-01A (Primary Tumor).

[page 1 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: M

PROCEDURE: SPHS

with endoscopy showing diagnosis of esophageal
adenocarcinoma - T3 N1 MX tumor. Biopsy of nodular tumor from 40-44 cm -
invasive moderately differentiated adenocarcinoma. Clinical Diagnosis:
Esophageal cancer. Operative Procedure: Transhiatal esophagectomy
(paraesophageal lymph node #1 is separate specimen).

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: esophagus, distal third C15.5

PROCEDURE: SPGD

1. "Distal esophagus and proximal stomach"

Received in a large container of formalin is a previously opened 11.8 cm
segment of distal esophagus and proximal stomach. Both margins are stapled.
The esophageal adventitia is focally firm, close to the esophagogastric
junction. The gastric serosa is also focally firm at this point. The
esophageal adventitia is inked green and the gastric serosa is inked black.
The focally nodular perigastric fat is stripped. A full thickness defect (1.6
x 0.3 cm) is found in the gastric cardia, within 0.4 cm of the EG junction.
Multiple incisions have been previously made with excision of some of the firm
tissue. This firm mass arising at the EG junction is 3.7 x 2.9 cm. Most of the
firm, multinodular mass involves the gastric side of the EG junction. The firm
area is not granular on the mucosal surface, yet appears to only involve the
submucosa. The cut surface shows a maximum thickness of 2.1 cm with extension
to the deep margin of the EG junction. The firm, submucosal mass is also
within 1.7 cm of the distal margin (blue). The multinodular mass involves 80%
of the circumference at the EG junction, including the area that was
previously excised. Extension and direct invasion involving the adventitia and
muscular wall, extending to within 0.7 cm of the distal margin. The remaining
esophageal and gastric mucosa is unremarkable. Lymph node candidates retrieved
from the paraesophageal and perigastric fat are found up to 3.2 cm in greatest
dimensions. The largest has a gray-tan to pink, firm cut surface that is
partly replaced with fatty tissue. Also lymph node candidates that are
calcified with a gray-black cut surface are retrieved. The calcified lymph
node is not sampled.

1A-C. Mass with proximal mucosa.

1D-F. Mass with deep and distal mucosa.

1G. Eight whole lymph node candidates.

1H. Six whole lymph node candidates.

1I. Bisected lymph node candidate.

1J. Representative sections of largest lymph node candidate.

Calcified lymph node candidate retained in biopsy bag and remainder of largest
lymph node candidate wrapped in gauze. Remaining fat retained.

2. "Cervical esophageal margin"

lw
10/7/12

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: M

Received in a small container of formalin is a 0.8 cm portion of esophagus that is stapled at one margin and open at the opposing margin. The adventitia is gray-tan to brown and focally hemorrhagic. The mucosa is unremarkable.

2A. Cervical esophageal margin.

3. "Paraesophageal lymph node #1"

Received in a small container of formalin is a 0.6 x 0.3 x 0.3 cm gray-black lymph node candidate with adherent fatty tissue.

3A. Paraesophageal lymph node #1.

4. "Paraesophageal lymph node"

Received in a small container of formalin are six ragged and irregular shaped portions of fatty tissue and soft tissue, aggregating to 2.9 x 2.5 x 0.5 cm. Fragments of lymph node candidate are within the ragged and irregular portions that are gray-black to tan. The largest portion is focally calcified.

4A. Lymph node candidate with adherent fatty tissue.

PROCEDURE: SPMI

ESOPHAGUS, GASTROESOPHAGEAL JUNCTION, INCLUDING CARDIA,
CARCINOMA (RESECTION SPECIMENS):

=====

LOCATION: Gastroesophageal junction, straddling the junction.

SIZE: 3.7 cm.

HAS IT BEEN TREATED PREOPERATIVELY WITH CHEMO/RADIATION THERAPY?: No.

TYPE OF CARCINOMA: Adenocarcinoma, cannot tell if Barrett's or not

DEPTH OF INVASION: Adventitia.

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 3/17.

NUMBER OF LYMPH NODES WITH SCAR BUT WITHOUT CARCINOMA CELLS POST-TREATMENT:
N.A.

DISTANT METASTASIS: Unknown.

RESECTION MARGIN INVOLVED: Narrowly free.

T3 N2

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 4
SEX: M

PROCEDURE: SPDX

1-2. Esophagus, esophagectomy and separately submitted cervical margin:
Invasive, poorly-differentiated adenocarcinoma (3.7 cm), extending into
adventitia. Metastatic carcinoma in three of fifteen lymph nodes (3/15).
Margins narrowly free. Please see TEMPLATE for details.

3. Lymph node, paraesophageal #1, excision: One lymph node negative for
carcinoma (0/1).

4. Lymph node, paraesophageal, excision: One lymph node negative for carcinoma
(0/1).

1, the signing staff pathologist, have personally
examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

	Yes	No
Current Discrepancy		
Previous Site Discrepancy		
Frequency		
Frequency History		
Continuous Primary Rpted		

Source: NCI Genomic Data Commons file 25e395d6-0286-4662-b0bb-2d02a8e89987 (TCGA-L5-A4OE.F6121788-C926-4A62-934A-882B6104AB6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).